Somatic mutation profile of tumor specimen TCGA-B5-A1MY-01A (aliquot TCGA-B5-A1MY-01A-11D-A142-09) from TCGA case TCGA-B5-A1MY, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IIIC2; Tumor grade: G3; Age at diagnosis: 62.4 years (22,805 days).
Specimen TCGA-B5-A1MY-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ec2f268e-3400-4557-9b0b-1a8a153f45cf.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B5-A1MY-10A (Blood Derived Normal), aliquot TCGA-B5-A1MY-10A-01D-A142-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/dc5390a6-72e9-47dd-817c-4b16e9c0069b

The open-access MAF lists 51 somatic variants for this specimen: 43 protein-altering or splice-affecting, 8 silent.
By variant classification: Missense Mutation 35, Silent 8, Nonsense Mutation 3, In Frame Del 2, Nonstop Mutation 1, Frame Shift Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AHNAK2 | c.15287G>T p.S5096I | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.3); catalogued as COSV60906828; called by muse, mutect2
- ALMS1 | c.11744G>T p.S3915I | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as COSV52501843; called by muse, mutect2, varscan2
- APP | c.469-2A>C p.X157_splice | Splice Site (SNP) | VAF 7/31 reads (23%) | catalogued as COSV60993116; called by muse, mutect2
- CAND2 | c.2286G>C p.Q762H (on ENST00000456430 / NM_001162499.2; = p.Q669H on NM_012298.3) | Missense Mutation (SNP) | VAF 16/25 reads (64%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.719); catalogued as COSV55986345; called by muse, mutect2, varscan2
- CDO1 | c.91G>C p.E31Q | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.947); catalogued as COSV51664209; called by muse, mutect2, varscan2
- CELF1 | c.238C>A p.H80N | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV60109831; called by muse, mutect2, varscan2
- CFAP69 | c.1448G>T p.S483I | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.075); catalogued as COSV60184036; called by muse, mutect2, varscan2
- CHL1 | c.766G>A p.E256K (on ENST00000397491 / NM_001253387.1; = p.E272K on NM_006614.4) | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.05); catalogued as rs776135822, COSV56585583; called by muse, mutect2, varscan2
- COX7B | c.119C>T p.A40V | Missense Mutation (SNP) | VAF 26/76 reads (34%) | SIFT tolerated (0.35); PolyPhen benign (0.015); catalogued as COSV64864479; called by muse, mutect2, varscan2
- CRBN | c.745G>A p.D249N | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.526); catalogued as COSV51639729; called by muse, mutect2, varscan2
- DDX31 | c.1786C>G p.Q596E | Missense Mutation (SNP) | VAF 38/51 reads (75%) | SIFT tolerated (0.17); PolyPhen benign (0.111); catalogued as COSV64648349; called by muse, mutect2, varscan2
- DDX53 | c.754G>A p.A252T | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.672); catalogued as rs371119636, COSV60068447; called by muse, mutect2, varscan2
- DNAH10 | c.2963A>C p.E988A (on ENST00000409039; = p.E927A on NM_207437.3) | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.029); catalogued as COSV68987441; called by muse, mutect2, varscan2
- DVL3 | c.634C>T p.R212C | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as rs778740365, COSV57454673; called by muse, mutect2, varscan2
- FAT1 | c.4797C>G p.Y1599* | Nonsense Mutation (SNP) | VAF 4/10 reads (40%) | catalogued as COSV71671707; called by muse, mutect2
- FLNC | c.1886G>A p.R629Q | Missense Mutation (SNP) | VAF 16/23 reads (70%) | SIFT deleterious (0.01); PolyPhen benign (0.371); catalogued as rs765173966, COSV57949682; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GIGYF2 | c.614G>A p.R205H | Missense Mutation (SNP) | VAF 35/65 reads (54%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as rs1452826937, COSV65246026; called by muse, mutect2, varscan2
- HADHA | c.78C>G p.C26W | Missense Mutation (SNP) | VAF 27/53 reads (51%) | SIFT tolerated (0.08); PolyPhen benign (0.401); catalogued as COSV66106206, COSV66107758; called by muse, mutect2, varscan2
- HADHA | c.77G>T p.C26F | Missense Mutation (SNP) | VAF 27/53 reads (51%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as COSV66106209; called by muse, mutect2, varscan2
- HNRNPA1 | c.178G>C p.V60L | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.436); catalogued as COSV52935490; called by muse, mutect2, varscan2
- HRH1 | c.181_186del p.V61_G62del | In Frame Del (DEL) | VAF 25/34 reads (74%) | catalogued as COSV67954979; called by mutect2, pindel, varscan2
- ICA1 | c.1196G>C p.G399A | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV55575680; called by muse, mutect2, varscan2
- LRRC3B | c.778T>C p.*260Qext*4 | Nonstop Mutation (SNP) | VAF 9/39 reads (23%) | catalogued as COSV67519907; called by muse, mutect2, varscan2
- LSS | c.634T>C p.F212L | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV62699798; called by muse, mutect2, varscan2
- MANBA | c.2576A>G p.D859G (on ENST00000642252; = p.D813G on NM_005908.4) | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.045); catalogued as COSV56962585; called by muse, mutect2, varscan2
- MYBPC3 | c.844C>T p.R282W | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.28); catalogued as rs727504234, CM014066, COSV57022525; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYOM1 | c.2942G>T p.G981V | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.984); catalogued as COSV55285030; called by muse, mutect2, varscan2
- NELFA | c.1462G>A p.V488M (on ENST00000542778; = p.V477M on NM_005663.5) | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.772); catalogued as rs752836647, COSV56386002; called by muse, mutect2, varscan2
- OR5R1 | c.728C>T p.S243F | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV56571386; called by muse, mutect2, varscan2
- OR5R1 | c.727T>C p.S243P | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV56571396; called by mutect2, varscan2
- ORM1 | c.455C>A p.T152N | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV52277801; called by muse, mutect2, varscan2
- PACS2 | c.1580C>T p.A527V | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.544); catalogued as rs782352968, COSV57649595; called by muse, mutect2
- PCDHA3 | c.497C>T p.S166L | Missense Mutation (SNP) | VAF 35/73 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.722); catalogued as rs35124371, COSV65364303; called by muse, mutect2, varscan2
- PECR | c.588C>G p.I196M | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV54733393; called by muse, mutect2, varscan2
- POLR2B | c.3040C>G p.L1014V | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT tolerated (0.32); PolyPhen benign (0.07); catalogued as COSV100107984, COSV58898438; called by muse, mutect2, varscan2
- PRKACG | c.811C>T p.R271W | Missense Mutation (SNP) | VAF 18/20 reads (90%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV55240702; called by muse, mutect2, varscan2
- SMAD3 | c.1274C>A p.S425Y | Missense Mutation (SNP) | VAF 13/21 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV59280131, COSV59281989, COSV59282869; called by mutect2, varscan2
- ST8SIA4 | c.140C>G p.S47* | Nonsense Mutation (SNP) | VAF 15/74 reads (20%) | catalogued as COSV51505485, COSV99185412; called by muse, mutect2, varscan2
- TAF4 | c.1777G>T p.V593L | Missense Mutation (SNP) | VAF 27/58 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53334024, COSV53343588; called by muse, mutect2, varscan2
- UTP20 | c.1048C>T p.Q350* | Nonsense Mutation (SNP) | VAF 31/59 reads (53%) | catalogued as COSV55371644; called by muse, mutect2, varscan2
- CDK12 | c.1647_1655del p.L554_P556del | In Frame Del (DEL) | VAF 26/102 reads (25%) | called by mutect2, pindel, varscan2
- SYNRG | c.1345C>G p.Q449E | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.208); called by muse, mutect2, varscan2
- UBAP2 | c.3022del p.S1008Afs*8 | Frame Shift Del (DEL) | VAF 20/43 reads (47%) | called by mutect2, pindel, varscan2
- ATG4D | c.960C>T p.C320= | Silent (SNP) | VAF 26/242 reads (11%) | catalogued as rs533372614, COSV57263438; called by muse, mutect2, varscan2
- CBL | c.2268C>T p.A756= | Silent (SNP) | VAF 5/26 reads (19%) | catalogued as rs142564074; called by muse, mutect2
- DAP3 | c.501T>C p.D167= | Silent (SNP) | VAF 16/78 reads (21%) | catalogued as COSV58019083; called by muse, mutect2, varscan2
- KCNQ2 | c.1239G>A p.P413= (on ENST00000359125 / NM_172107.4; = p.P403= on NM_004518.6) | Silent (SNP) | VAF 10/22 reads (45%) | catalogued as rs372146620, COSV60539612; ClinVar: likely benign; called by muse, mutect2, varscan2
- KRT38 | c.327G>A p.Q109= | Silent (SNP) | VAF 15/73 reads (21%) | catalogued as COSV55845106; called by muse, mutect2, varscan2
- PCDHGA1 | c.1524C>T p.N508= | Silent (SNP) | VAF 16/66 reads (24%) | catalogued as COSV65294792; called by muse, mutect2, varscan2
- TMEM215 | c.291C>A p.T97= | Silent (SNP) | VAF 6/17 reads (35%) | catalogued as rs1313866478, COSV61363129; called by muse, mutect2, varscan2
- ZNF623 | c.1503C>T p.N501= | Silent (SNP) | VAF 9/24 reads (38%) | catalogued as rs373603798, COSV71697070; called by muse, mutect2, varscan2
